TCGA case TCGA-DD-AAVX — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/afcb9708-92b3-4727-9c0d-63e7ff22d87b

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: South Korea; Age at index: 38 years; Vital status: Alive.

Diagnoses (3)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 38.4 years (14,016 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,718 days (4.7 years); Child pugh classification: A; Ishak fibrosis score: 6 - Established Cirrhosis.
   Pathology details: Additional pathology findings: Inflammation; Consistent pathology review: Yes; Vascular invasion present: Yes; Vascular invasion type: Micro.
   Treatment given: Treatment type: Ablation or Embolization, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Bone, NOS. Age at diagnosis: 39.4 years (14,409 days); Days to diagnosis: 393 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Surgery, NOS, for recurrent disease.
3. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 39.4 years (14,409 days); Days to diagnosis: 393 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Ablation or Embolization, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease; Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (5 entries)
- Day 393 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone, NOS; Days to recurrence: 393 days (1.1 years).
- Day 393 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Liver; Days to recurrence: 393 days (1.1 years).
- Days to follow up: 1,570 days (4.3 years); Disease response: With Tumor.
- Days to follow up: 1,718 days (4.7 years); Disease response: With Tumor.
- ECOG performance status: 0.

Molecular and laboratory tests
- Creatinine 1 mg/dL [Blood test normal range lower: 0.7; Blood test normal range upper: 1.4].
- Alpha Fetoprotein 1 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 15].
- Total Bilirubin 1.1 mg/dL [Blood test normal range lower: 0.2; Blood test normal range upper: 1.2].
- Platelets 186 (unit not recorded by GDC) [Blood test normal range lower: 130; Blood test normal range upper: 400].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1 [Blood test normal range lower: 0.8; Blood test normal range upper: 1.2].
- Albumin 3.9 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.3; Blood test normal range upper: 5.2].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Hepatitis B Infection.
- Timepoint category: Initial Diagnosis; Weight: 65 kg; Height: 178 cm; BMI: 20.5.

Family history
- Relatives with cancer history count: 2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DD-AAVX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 50 mg.
  Slide TCGA-DD-AAVX-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 4.
- Sample TCGA-DD-AAVX-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DD-AAVX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Multiple; Hepatic inflammation adj tissue: Severe.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,718 days; disease-specific survival: no event (censored), 1,718 days; disease-free interval: event (new tumor event after initially disease-free), 393 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 393 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DD-AAVX-01A-11D-A40Q-01): tumor purity 0.73, ploidy 2.13, whole-genome doublings 0.
